Surgical pathology report (de-identified scan), TCGA case TCGA-24-0980, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-0980-01A (Primary Tumor).

[page 1 of 4]
Surgical Pathology Report

Final

SURGICAL PATHOLOGY REPORT

Physician(s):

Other Related Clinical Data:

DIAGNOSIS:

- A. OMENTUM, OMENTECTOMY
- METASTATIC POORLY DIFFERENTIATED ADENOCARCINOMA, LARGEST FOCUS 8 CM
- B. SMALL INTESTINE, RESECTION
- METASTATIC POORLY DIFFERENTIATED ADENOCARCINOMA, INVOLVING SEROSA & MUSCULARIS PROPRIA
- LYMPHOVASCULAR INVASION IDENTIFIED
- RESECTION MARGINS FREE-OF TUMOR
- ACUTE SEROSITIS
- C. OVARIES, RIGHT & LEFT, BILATERAL SALPINGO-OOPHORECTOMY
- POORLY DIFFERENTIATED ADENOCARCINOMA, WITH MIXED SEROUS PAPILLARY & POORLY DIFFERENTIATED ENDOMETRIOID FEATURES, SYNCHRONOUS PRIMARIES (SEE SYNOPTIC)
- 10 CM & 11.5 CM IN GREATEST DIMENSION
- POORLY DIFFERENTIATED ADENOCARCINOMA PRESENT ON BOTH OVARIAN SURFACES
- FALLOPIAN TUBES, RIGHT & LEFT, BILATERAL SALPINGO-OOPHORECTOMY
- METASTATIC POORLY DIFFERENTIATED ADENOCARCINOMA INVOLVING PARATUBAL SOFT TISSUE WITH INTRALUMINAL INVOLVEMENT OF ONE FALLOPIAN TUBE (NOT OTHERWISE SPECIFIED)
- D. UTERUS, CERVIX, TOTAL ABDOMINAL HYSTERECTOMY
- NABOTHIAN CYSTS AND TUNNEL CLUSTERS
- NO EVIDENCE OF MALIGNANCY
- UTERUS, ENDOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY
- ATROPHIC ENDOMETRIUM
- NO EVIDENCE OF MALIGNANCY
- UTERUS, MYOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY
- ADENOMYOSIS
- UTERUS, SEROSA, TOTAL ABDOMINAL HYSTERECTOMY
- METASTATIC POORLY DIFFERENTIATED ADENOCARCINOMA WITH LYMPHOVASCULAR INVASION IDENTIFIED
- SEROSAL ADHESIONS

By this signature, I attest that the above diagnosis is

[page 2 of 4]
based upon my personal
examination of the slides (and/or other material indicated in the
diagnosis).

***Report Electronically Reviewed and Signed Out By :
Intraoperative Consultation:
Tissue for tumor bank collected. By .
Omentum, biopsy - "Carcinoma, favor Mullerian origin," by

Microscopic Description and Comment:
Microscopic examination substantiates the above cited diagnosis.

History:

The patient is a year old woman with an abdominal mass. Operative procedure:
EUA, exploratory laparotomy, small bowel resection, total abdominal
hysterectomy, bilateral salpingo-oophorectomy, tumor debulking, and omentectomy.
Specimen(s) Received:

- A: OMENTUM
- B: SMALL BOWEL
- C: RIGHT AND LEFT OVARIES
- D: UTERUS AND CERVIX

Gross Description

The specimens are received in four formalin-filled containers, each labeled with
the patient's name " ". The first container is also labeled "omentum,
FS1/X." It contains a white cassette labeled "FS1," that holds two fragments of
firm, tan tissue, measuring from 0.9 cm and 1.9 x 1.4 x 0.2 cm. Labeled A1
(FS1). Also within the container is a previously sectioned fragment of omentum,
measuring 11 x 6 x 2 cm. A firm, tan-white nodule, measuring 8 cm in greatest
dimension is embedded in the middle of the omentum, consistent with metastasis.
Labeled A2. Jar 2.

The second container is labeled "small bowel." It contains an unoriented
segment of small bowel, measuring 25 cm in length and 3.5 cm in diameter. A
kink is present in the middle of the segment and there are adhesions present
between the bowel loops. Two staple lines, each measuring 3 cm in length, are
identified on either end of the segment. There are yellow-white fibrinoid
exudate present on the serosal surface, along with multiple omental nodules,
measuring from 1 cm to 11 cm in greatest dimension. The segment is opened to
show unremarkable mucosa with no apparent tumor present on the mucosal surface.
Also within the container are multiple fragments of firm, tan-yellow-white
tissue, measuring from 2 cm to 9 cm in greatest dimension. Sections show firm,
white tissue, consistent with metastases. Labeled B1 - one resection margin; B2
- the other resection margin; B3 to B5 - section of omental mass with surface
mucosa; B6 - mucosa with serosal fibrinoid exudate; B7, B8 - sections of
separate fragment in the container. Jar 3.

The third container is labeled "R and L ovaries." It contains two unlabeled
cystic ovarian masses, measuring 10 x 8 x 4 cm and 11.5 x 10 x 5 cm. There are
yellow-white fibrinoid exudate as well as firm white masses present on both
ovarian surfaces. Area of rupture are present on both surfaces of the ovary as
well. A segment of fallopian tube, measuring 4.5 cm in length x 0.5 cm in
diameter is identified in the smaller ovary. Sections of the fallopian tube
show no obvious tumor involvement. A 10 cm long fallopian tube is also
identified with the larger ovary and the distal 2/3 of fallopian tube is
severely dilated and with tumor inside the lumen, having a maximum diameter of 4

[page 3 of 4]
cm. Labeled C1 to C5 - random sections of smaller cystic ovarian mass (C1 includes ruptured area); C6 - random section of the fallopian tube attached to the smaller ovarian mass; C7 to C11 - sections of the larger cystic ovarian mass (C11 includes surface rupture); C12 - junction between the larger ovary and fallopian tube; C13 to C15 - sections of fallopian tube (C13, C14 includes tumor) attached to the large ovary. Jar 3.

The fourth container is labeled "uterus, cervix." It contains a uterus with attached partial cervix and without adnexae, measuring 9 cm from fundus to exocervix, 5 cm from cornu to cornu, and 5 cm from anterior to posterior. The uterus weighs 129 grams. There are surface adhesions present on both anterior and posterior serosa. There are white, firm masses in the right adnexa area. A minimal exocervix is present, and covered by fleshy white mucosa, measuring 0.7 cm x 0.4 cm with a slit-like os. The resection margin is inked blue. Two Nabothian cysts are present in the left lateral endocervix. The uterus is bivalved to show unremarkable endometrial cavity, measuring 1.5 cm in width and 4 cm in length. The endometrium has a thickness of 0.1 cm and the myometrium has a thickness of 1-2 cm. Further sections show no additional lesions identified. Labeled D1 - anterior cervix/endocervix; D2 - posterior cervix/endocervix; D3 - Nabothian cysts; D4 - anterior endomyometrium; D5 - posterior endomyometrium; D6 - serosal adhesions; D7 - sections of right adnexal firm mass. Jar 2.

Synopsis

SYNOPTIC REPORTING FORM FOR MALIGNANT OVARIAN NEOPLASMS

1. A neoplasm is PRESENT
2. The HISTOLOGIC DIAGNOSIS is:
Serous adenocarcinoma AND Endometrioid adenocarcinoma
3. The LOCATION(S) OF THE PRIMARY TUMOR(S) is/are:
Right and left ovary (synchronous primary tumors)
4. The FIGO GRADE of the tumor is:
III (Tumor composed of >50% solid cellular nests)
5. The NUCLEAR (BRODERS') GRADE of the tumor is:
G3 (Poorly-differentiated)
6. Tumor IS identified on the ovarian surface(s).
7. Tumor DOES invade the mesovarium.
8. Tumor DOES invade the adjacent fallopian tube.
9. Tumor invasion of pelvic soft tissue CANNOT BE EVALUATED.
10. Tumor involvement of the pelvic peritoneum CANNOT BE EVALUATED.
11. Metastatic involvement of the EXTRAPELVIC PERITONEUM is PRESENT.
12. Metastatic involvement of the omentum is PRESENT.
13. The maximum dimension of tumor implants outside the true pelvis is 11.0 cm (omentum).
14. Metastatic involvement of the uterine serosa is PRESENT.
15. Metastatic involvement of the endometrium is ABSENT.
16. Regional lymph node metastases CANNOT BE EVALUATED.
17. The total number of regional lymph nodes examined is 0.
18. The total number of metastatically-involved regional lymph nodes is NOT EVALUABLE.
19. DETAILED STAGING INFORMATION:

Based on the above information, the PRIMARY TUMOR is classified as:

TNM Scheme	FIGO Scheme	Definition
T3c	IIIC	Macroscopic
peritoneal metastasis beyond true pelvis measuring > 2 cm in greatest dimension		

[page 4 of 4]
THE REGIONAL LYMPH NODES are classified as:

NX (Nodal status cannot be assessed)

THE STATUS OF DISTANT TUMOR SITES is classified as:

MX (Status cannot be assessed)

20. The FINAL AJCC/UICC/FIGO STAGE IS:

AJCC/UICC/FIGO

X

Insufficient data to assign stage

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

Source: NCI Genomic Data Commons file 6eb9e1b5-eb38-4bf0-8e69-42959a3689ec (TCGA-24-0980.8C40A7D6-AAE5-4105-95D3-B841008F6FA6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).